Somatic mutation profile of tumor specimen MMRF_1300_1_BM_CD138pos (aliquot MMRF_1300_1_BM_CD138pos_T1_KAS5U_L01217) from MMRF case MMRF_1300, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.2 years (22,705 days).
Specimen MMRF_1300_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff5ec46d-c0ac-4a76-b356-0b9f5b671f22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1300_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1300_1_PB_Whole_C2_KAS5U_L01228; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae7f3d52-ff9b-4495-81ee-473ae54e05f3

The open-access MAF lists 144 somatic variants for this specimen: 71 protein-altering or splice-affecting, 15 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, 3'UTR 35, Silent 15, Intron 14, 5'UTR 4, 5'Flank 3, Nonsense Mutation 3, RNA 2, Frame Shift Del 2, Translation Start Site 1, Splice Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886043613, CM066080, COSV53390215; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAMTS13 | c.2807C>T p.A936V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV63020285; called by muse, mutect2
- ADAMTS15 | c.2566G>A p.G856S | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1224961919; called by muse, mutect2, varscan2
- ADGRE3 | c.447G>T p.W149C | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.682); catalogued as COSV53730767; called by muse, mutect2, varscan2
- ASPDH | c.424G>A p.G142S | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0.354); catalogued as rs1239591537; called by muse, mutect2, varscan2
- CCR7 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as rs764674952; called by muse, mutect2, varscan2
- CDHR4 | c.100G>T p.G34C | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58526672; called by muse, mutect2
- CFAP46 | c.5782C>T p.R1928W | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs762437213, COSV54160036; called by muse, mutect2, varscan2
- DIS3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 36/36 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750002908; called by muse, mutect2, varscan2
- FGFR3 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53426972, COSV99603109; called by muse, mutect2, varscan2
- GMIP | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 132/191 reads (69%) | SIFT tolerated (0.19); PolyPhen benign (0.13); catalogued as rs1341478234; called by muse, mutect2, varscan2
- IGKV4-1 | c.283A>C p.T95P | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs578059335; called by muse, mutect2, varscan2
- NSD2 | c.2449T>G p.F817V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1560757150; called by muse, mutect2, varscan2
- PCDHGA4 | c.599G>A p.G200D | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.978); catalogued as rs568835897; called by muse, mutect2, varscan2
- PIKFYVE | c.5641C>T p.R1881C | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs962586024, COSV52252734; called by muse, mutect2, varscan2
- SACS | c.4840T>C p.F1614L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.28); catalogued as rs771080306; called by muse, mutect2, varscan2
- SEMA4G | c.1861G>A p.D621N (on ENST00000370250; = p.D626N on NM_017893.3) | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.152); catalogued as COSV52968081; called by muse, mutect2, varscan2
- SYMPK | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.939); catalogued as rs773604683, COSV55610343; called by muse, mutect2, varscan2
- TFB2M | c.862T>A p.L288I | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as rs1474223751; called by muse, mutect2
- TRAV25 | c.47-2A>C p.X16_splice | Splice Site (SNP) | VAF 30/68 reads (44%) | catalogued as rs1427794774; called by muse, mutect2, varscan2
- TTN | c.12701C>T p.P4234L (on ENST00000591111; = p.P4188L on NM_003319.4) | Missense Mutation (SNP) | VAF 54/184 reads (29%) | catalogued as COSV100617053, COSV59947898; called by muse, mutect2, varscan2
- ADCY8 | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ADGRE3 | c.446G>T p.W149L | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AKR1C8P | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | called by mutect2, varscan2
- ALPK1 | c.1295A>T p.Y432F | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- AP3M1 | c.165C>A p.Y55* | Nonsense Mutation (SNP) | VAF 15/141 reads (11%) | called by muse, mutect2, varscan2
- APBA3 | c.1065G>C p.Q355H | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ARSD | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C12orf50 | c.733C>G p.L245V | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CAPN14 | c.1667T>C p.F556S | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- CDC25C | c.616G>T p.V206L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEACAM7 | c.733del p.D245Tfs*11 | Frame Shift Del (DEL) | VAF 29/191 reads (15%) | called by mutect2, pindel*, varscan2
- CHD4 | c.1004C>A p.S335Y | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- CSMD2 | c.1346A>C p.E449A | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- DGKB | c.440G>A p.R147K | Missense Mutation (SNP) | VAF 56/97 reads (58%) | SIFT tolerated (0.38); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- DHRS9 | c.775A>C p.M259L | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH2 | c.12801_12825del p.W4267* | Frame Shift Del (DEL) | VAF 15/91 reads (16%) | called by mutect2, pindel
- EAPP | c.452T>C p.V151A | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ELFN1 | c.533G>A p.G178D | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EMP3 | c.389C>A p.P130Q | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- FBN2 | c.7362G>T p.K2454N | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FER1L5 | c.658G>T p.V220F | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GLP1R | c.280A>G p.S94G | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.047); called by muse, mutect2
- GPR161 | c.358G>T p.V120F | Missense Mutation (SNP) | VAF 10/185 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.185); called by muse, mutect2
- HCRTR1 | c.209C>A p.A70D | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGKV5-2 | c.287A>G p.N96S | Missense Mutation (SNP) | VAF 50/78 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, varscan2
- IL16 | c.2957A>G p.K986R (on ENST00000302987 / NM_172217.5; = p.K285R on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- KIAA0319 | c.1949G>A p.S650N | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2
- LBX1 | c.599G>C p.S200T | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRGUK | c.2285G>A p.G762E | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2
- LY75 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.18); called by muse, mutect2
- MCM3AP | c.2443C>T p.L815F | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PARP14 | c.1568A>G p.E523G | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- PCDH11X | c.1534G>T p.E512* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2, varscan2
- PCDH11X | c.1535A>C p.E512A | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PCDHA12 | c.2008G>T p.V670L | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- PEPD | c.1482G>C p.*494Yext*19 | Nonstop Mutation (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- POLK | c.2068C>T p.P690S | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SAMD8 | c.222A>T p.K74N | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.062); called by muse, mutect2
- SETD2 | c.4750C>T p.L1584F | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- SGPP1 | c.578A>G p.K193R | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SIGLEC7 | c.746A>G p.Q249R | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- SLC7A4 | c.215T>A p.L72H | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2
- SMCHD1 | c.4372G>A p.G1458R | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMF1 | c.3236T>C p.M1079T | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TNRC6A | c.797G>C p.R266T | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- UPF1 | c.2713G>A p.E905K (on ENST00000599848 / NM_001297549.2; = p.E894K on NM_002911.4) | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2
- ZBTB21 | c.1088A>G p.Q363R | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZFHX4 | c.1162A>T p.T388S | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZGLP1 | c.157T>C p.S53P | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2
- ZNF222 | c.134T>G p.L45R | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALDH1A2 | c.198G>A p.V66= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as rs1201182915, COSV51094719; called by muse, mutect2, varscan2
- CASP8 | c.711G>A p.L237= (on ENST00000432109 / NM_033355.3; = p.L254= on NM_001228.4) | Silent (SNP) | VAF 17/117 reads (15%) | called by muse, mutect2, varscan2
- CEP97 | c.1134T>C p.S378= | Silent (SNP) | VAF 65/160 reads (41%) | called by muse, mutect2, varscan2
- DNAH5 | c.951G>A p.A317= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs768621532, COSV99447175; called by muse, varscan2
- GPR148 | c.981G>A p.L327= | Silent (SNP) | VAF 42/120 reads (35%) | catalogued as rs1175155569; called by muse, mutect2, varscan2
- IFFO2 | c.504G>T p.R168= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs1284049710; called by muse, mutect2
- IGHV1-69D | c.93G>A p.K31= | Silent (SNP) | VAF 6/13 reads (46%) | called by mutect2, varscan2
- ITGAD | c.2226C>A p.S742= | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as COSV66757043; called by muse, mutect2, varscan2
- NEK3 | c.852G>T p.S284= | Silent (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- OR5H15 | c.315A>C p.A105= | Silent (SNP) | VAF 57/184 reads (31%) | called by muse, mutect2
- PIEZO2 | c.5586C>A p.R1862= | Silent (SNP) | VAF 29/114 reads (25%) | called by muse, mutect2, varscan2
- PKNOX1 | c.1164G>A p.S388= | Silent (SNP) | VAF 46/85 reads (54%) | catalogued as rs531349610, COSV104394780; called by muse, mutect2, varscan2
- RYR1 | c.8577C>T p.P2859= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as rs1414350170, COSV62090034; called by muse, mutect2, varscan2
- TARS3 | c.1986G>A p.K662= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs961091019; called by muse, mutect2, varscan2
- ZBTB10 | c.1896T>G p.G632= | Silent (SNP) | VAF 31/68 reads (46%) | called by muse, mutect2, varscan2
- ADGRL4 | c.*699dup | 3'UTR (INS) | VAF 8/42 reads (19%) | catalogued as rs1168259205; called by mutect2, varscan2
- ALG3 | chr3:184249208 A>G | 5'Flank (SNP) | VAF 63/234 reads (27%) | catalogued as rs1170720590; called by muse, mutect2, varscan2
- BLK | c.473-1468C>G | Intron (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- BMP3 | c.*2544A>G | 3'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- BMP6 | c.*1310T>C | 3'UTR (SNP) | VAF 20/139 reads (14%) | called by muse, mutect2, varscan2
- BRINP3 | c.*126A>T | 3'UTR (SNP) | VAF 17/43 reads (40%) | called by muse, mutect2, varscan2
- BTBD11 | c.*633A>T | 3'UTR (SNP) | VAF 5/50 reads (10%) | catalogued as rs1182445159, COSV99776221; called by muse, mutect2
- CARD11 | c.*340G>A | 3'UTR (SNP) | VAF 16/160 reads (10%) | called by muse, mutect2
- CCDC42 | c.*90G>C | 3'UTR (SNP) | VAF 4/15 reads (27%) | catalogued as rs1198669982; called by muse, mutect2, varscan2
- CFAP92 | c.*886A>T | 3'UTR (SNP) | VAF 13/94 reads (14%) | called by muse, mutect2, varscan2
- CLBA1 | c.*453C>T | 3'UTR (SNP) | VAF 11/75 reads (15%) | called by muse, mutect2, varscan2
- CLK1 | c.549-88_549-77del | Intron (DEL) | VAF 46/127 reads (36%) | called by mutect2, pindel, varscan2
- CLRN3 | c.-6G>A | 5'UTR (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- EPOP | c.*1003C>T | 3'UTR (SNP) | VAF 36/71 reads (51%) | called by muse, mutect2, varscan2
- EREG | c.*3637A>C | 3'UTR (SNP) | VAF 13/61 reads (21%) | called by muse, mutect2, varscan2
- FAM3C | c.382+34T>A | Intron (SNP) | VAF 18/57 reads (32%) | called by muse, mutect2, varscan2
- FLJ40288 | n.1168T>A | RNA (SNP) | VAF 33/76 reads (43%) | called by muse, mutect2, varscan2
- FLRT1 | c.*701_*731del | 3'UTR (DEL) | VAF 29/65 reads (45%) | called by mutect2, pindel, varscan2
- GBA2 | c.2055-70A>G | Intron (SNP) | VAF 82/203 reads (40%) | catalogued as rs761919429, COSV100803503; called by muse, mutect2, varscan2
- GCK | c.46-4630C>A | Intron (SNP) | VAF 10/145 reads (7%) | called by muse, mutect2
- GNB1L | c.*4626C>T | 3'UTR (SNP) | VAF 8/31 reads (26%) | catalogued as rs1017860222; called by muse, mutect2, varscan2
- GRAMD2B | c.*90G>A | 3'UTR (SNP) | VAF 6/130 reads (5%) | called by muse, mutect2
- HAUS6 | c.*3064T>G | 3'UTR (SNP) | VAF 80/255 reads (31%) | called by muse, mutect2, varscan2
- HEATR9 | c.567+158T>C | Intron (SNP) | VAF 6/8 reads (75%) | catalogued as rs1568324175; called by muse, mutect2, varscan2
- HIPK2 | c.*7777T>G | 3'UTR (SNP) | VAF 13/87 reads (15%) | called by muse, mutect2, varscan2
- IRF5 | c.*63G>A | 3'UTR (SNP) | VAF 45/65 reads (69%) | called by muse, mutect2, varscan2
- LAMC2 | c.*1198C>A | 3'UTR (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- LINC01555 | n.955C>T | RNA (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- MAGEB10 | c.-7A>C | 5'UTR (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- MAN1A1 | c.*2542G>A | 3'UTR (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- MBL2 | c.*114G>T | 3'UTR (SNP) | VAF 6/26 reads (23%) | catalogued as rs1458834863; called by muse, mutect2, varscan2
- MRPL40 | c.-22C>A | 5'UTR (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- NOP2 | c.239-9A>G | Intron (SNP) | VAF 24/146 reads (16%) | catalogued as COSV58896212; called by muse, mutect2, varscan2
- NR2F2 | c.*609T>C | 3'UTR (SNP) | VAF 35/59 reads (59%) | called by muse, mutect2, varscan2
- PCBP2 | c.*81C>T | 3'UTR (SNP) | VAF 3/51 reads (6%) | catalogued as rs1565878065; called by muse, mutect2
- PDE4DIP | c.2815+3636T>C | Intron (SNP) | VAF 11/216 reads (5%) | called by muse, mutect2
- PGM3 | c.*3971A>T | 3'UTR (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- PIGZ | c.*578A>G | 3'UTR (SNP) | VAF 17/95 reads (18%) | called by muse, mutect2, varscan2
- PPP1R37 | c.1296+13C>T | Intron (SNP) | VAF 16/112 reads (14%) | catalogued as rs763966523; called by muse, mutect2, varscan2
- RAB11FIP1 | c.*1645G>A | 3'UTR (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- RACGAP1 | c.*46A>G | 3'UTR (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2, varscan2
- ROBO1 | c.*943_*948del | 3'UTR (DEL) | VAF 3/22 reads (14%) | called by pindel, varscan2*
- S1PR3 | c.-148+4261T>A | Intron (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- SCML4 | c.682+4882C>A | Intron (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2
- SELENBP1 | c.*50G>A | 3'UTR (SNP) | VAF 14/56 reads (25%) | catalogued as COSV100923629; called by mutect2, varscan2
- SLC35F3 | c.*998A>G | 3'UTR (SNP) | VAF 38/90 reads (42%) | catalogued as rs949306223; called by muse, varscan2
- SPRR3 | c.*220T>C | 3'UTR (SNP) | VAF 7/94 reads (7%) | called by muse, mutect2
- SYT15 | chr10:46578508 G>A | 5'Flank (SNP) | VAF 18/29 reads (62%) | called by mutect2, varscan2
- TIMM17A | c.*51A>G | 3'UTR (SNP) | VAF 69/232 reads (30%) | called by muse, mutect2, varscan2
- TMEM130 | c.*1219C>A | 3'UTR (SNP) | VAF 18/79 reads (23%) | called by muse, mutect2, varscan2
- TMOD1 | c.397+2221T>C | Intron (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2
- TMSB4X | chrX:12975605 A>G | 5'Flank (SNP) | VAF 64/66 reads (97%) | called by muse, mutect2, varscan2
- TNFRSF10C | c.*296C>T | 3'UTR (SNP) | VAF 51/94 reads (54%) | called by muse, mutect2, varscan2
- TOMM20 | c.*2510G>C | 3'UTR (SNP) | VAF 10/93 reads (11%) | called by muse, mutect2, varscan2
- TPMT | c.-10C>T | 5'UTR (SNP) | VAF 29/185 reads (16%) | catalogued as COSV100015332; called by muse, mutect2, varscan2
- UBXN6 | c.615+23G>A | Intron (SNP) | VAF 8/24 reads (33%) | catalogued as rs776364037; called by muse, mutect2, varscan2
- UROS | c.395-3990A>G | Intron (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- ZNF592 | c.*640T>A | 3'UTR (SNP) | VAF 17/86 reads (20%) | called by muse, mutect2, varscan2
